CCDI case PBCLHE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9c461207-c013-4663-8a4d-55a32f57adf8

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,654 days).

Biospecimens (2 samples)
- Sample 0DUIWQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUIX9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
